Somatic mutation profile of tumor specimen MMRF_1610_1_BM_CD138pos (aliquot MMRF_1610_1_BM_CD138pos_T2_KBS5U_L05361) from MMRF case MMRF_1610, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.0 years (19,357 days).
Specimen MMRF_1610_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93092118-c9f2-46be-b04d-50f3e046fc56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1610_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1610_1_PB_Whole_C3_KBS5U_L05357; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86b8e675-857a-4c2f-b9ed-3486d00af812

The open-access MAF lists 70 somatic variants for this specimen: 20 protein-altering or splice-affecting, 14 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, 3'UTR 15, Silent 14, Intron 10, 3'Flank 4, Nonsense Mutation 3, 5'UTR 3, 5'Flank 2, IGR 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 26/167 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- FPR1 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV100494080, COSV59050974; called by muse, mutect2, varscan2
- GATAD1 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1261746364, COSV55319491; called by muse, mutect2
- H2BC12 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.024); catalogued as rs759189956, COSV63616656; called by muse, mutect2, varscan2
- HMCN1 | c.5119C>T p.R1707* | Nonsense Mutation (SNP) | VAF 54/109 reads (50%) | catalogued as COSV54899014; called by muse, mutect2, varscan2
- IGHJ3 | c.32T>C p.M11T | Missense Mutation (SNP) | VAF 32/46 reads (70%) | PolyPhen benign (0); catalogued as rs181332275; called by muse, mutect2, varscan2
- IGHV2-70 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs377473012; called by muse, varscan2
- IGHV3-23 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.022); catalogued as rs377421865; called by muse, varscan2
- RAD54L2 | c.3574C>A p.R1192S | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); catalogued as rs200912618, COSV56579726; called by muse, mutect2, varscan2
- SHROOM3 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1195051559; called by muse, mutect2, varscan2
- SLIT2 | c.3676G>A p.A1226T | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV99888330; called by muse, mutect2, varscan2
- SNTG1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs764592457, COSV99387366; called by muse, mutect2, varscan2
- TARS1 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs769876534; called by muse, varscan2
- CD44 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- EVC | c.721A>T p.K241* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV3-23 | c.48T>C p.G16= | Splice Region (SNP) | VAF 44/150 reads (29%) | called by muse, mutect2, varscan2
- PRDX3 | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZFHX4 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF512B | c.1781T>C p.L594P | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AGRN | c.3201C>T p.S1067= | Silent (SNP) | VAF 65/143 reads (45%) | catalogued as rs781405874, COSV65072307; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.225G>C p.L75= | Silent (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- FAM122B | c.743G>A p.*248= (on ENST00000370790 / NM_001166599.3; = p.*249= on NM_145284.5) | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- H4C12 | c.225G>A p.E75= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as rs776999590; called by muse, mutect2, varscan2
- IGHJ3 | c.15C>T p.I5= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs374840426; called by muse, varscan2
- IL1A | c.405C>A p.I135= | Silent (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- KL | c.2172G>T p.G724= | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as COSV66308134; called by muse, mutect2, varscan2
- MED13L | c.2838A>C p.G946= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- NEURL1 | c.633G>A p.R211= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV100872831; called by muse, mutect2, varscan2
- PLCXD1 | c.273C>T p.D91= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs1420905878; called by muse, mutect2, varscan2
- PPIP5K2 | c.1680C>T p.L560= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as rs782513775, COSV58610338; called by muse, mutect2, varscan2
- RCN3 | c.351G>C p.S117= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs762154898; called by muse, mutect2, varscan2
- RIPOR2 | c.24G>A p.E8= | Silent (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- SPR | c.363C>T p.N121= | Silent (SNP) | VAF 60/148 reads (41%) | called by muse, mutect2, varscan2
- AC093512.2 | c.*1134-21C>T | Intron (SNP) | VAF 114/247 reads (46%) | catalogued as rs370909055; called by muse, mutect2, varscan2
- AGK | c.*52A>G | 3'UTR (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- AK6 | c.*143C>G | 3'UTR (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.2654-52G>T | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- ATP5MPL | c.148+242A>C | Intron (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021715 C>A | 5'Flank (SNP) | VAF 20/28 reads (71%) | called by muse, varscan2
- BET1L | c.*1511A>T | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- BMPR1B | chr4:95155573 A>G | 3'Flank (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- C8orf34 | c.1105+1703G>A | Intron (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- CDK6 | c.*8442A>T | 3'UTR (SNP) | VAF 57/107 reads (53%) | called by muse, mutect2, varscan2
- CHST11 | c.-97C>T | 5'UTR (SNP) | VAF 57/123 reads (46%) | catalogued as rs1024521294; called by muse, mutect2, varscan2
- CRIP1 | c.193+27C>T | Intron (SNP) | VAF 49/140 reads (35%) | called by muse, mutect2, varscan2
- CTNND2 | c.*702T>G | 3'UTR (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- ECHDC1 | c.434+153C>T | Intron (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- EMP2 | c.*871T>C | 3'UTR (SNP) | VAF 89/210 reads (42%) | called by muse, mutect2, varscan2
- ENPEP | c.*853G>T | 3'UTR (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- ENPEP | c.*2879A>T | 3'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- FOLH1B | n.843G>T | RNA (SNP) | VAF 42/124 reads (34%) | called by muse, mutect2, varscan2
- H3C4 | c.-34T>G | 5'UTR (SNP) | VAF 61/113 reads (54%) | catalogued as rs772461329; called by muse, mutect2, varscan2
- HS3ST1 | c.*2043A>T | 3'UTR (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- HTR5A | c.-396A>C | 5'UTR (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- IGLV3-1 | chr22:22881397 del GTGACACAGGCAGATG | 3'Flank (DEL) | VAF 34/84 reads (40%) | called by pindel, varscan2
- IRX3 | c.268-46del | Intron (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- LRRTM4 | chr2:76748270 A>T | 3'Flank (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2
- MIR5195 | chr14:106851279 T>C | 5'Flank (SNP) | VAF 78/163 reads (48%) | catalogued as rs780130264; called by muse, mutect2, varscan2
- MYOM2 | c.4025-46A>T | Intron (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- NHSL2 | chrX:72143670 C>T | 3'Flank (SNP) | VAF 23/26 reads (88%) | called by muse, mutect2
- NTRK3 | c.*8366G>A | 3'UTR (SNP) | VAF 15/42 reads (36%) | catalogued as rs771353579; called by muse, mutect2, varscan2
- PATL1 | c.*615T>A | 3'UTR (SNP) | VAF 7/90 reads (8%) | catalogued as rs1314724096; called by muse, mutect2
- PRDM4 | c.*24G>A | 3'UTR (SNP) | VAF 79/165 reads (48%) | called by muse, mutect2, varscan2
- PTPA | c.*1163C>T | 3'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- SCAF11 | c.-21-11524C>G | Intron (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2
- SLC6A7 | c.*176C>T | 3'UTR (SNP) | VAF 42/77 reads (55%) | called by muse, mutect2, varscan2
- STK4 | c.1306-21856C>G | Intron (SNP) | VAF 79/178 reads (44%) | catalogued as rs758465524; called by muse, mutect2, varscan2
- UBR3 | c.*1959A>T | 3'UTR (SNP) | VAF 42/83 reads (51%) | catalogued as rs553839274; called by muse, mutect2, varscan2
- Unknown | chr1:200342546 del C | IGR (DEL) | VAF 19/68 reads (28%) | catalogued as rs374198468; called by mutect2, pindel, varscan2
